Somatic mutation profile of tumor specimen MMRF_1332_3_BM_CD138pos (aliquot MMRF_1332_3_BM_CD138pos_T1_KBS5U_L05839) from MMRF case MMRF_1332, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.0 years (12,044 days).
Specimen MMRF_1332_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c757b93-5e7b-4151-bcff-96700f964bea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1332_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1332_1_PB_Whole_C2_KHS5U_L15101; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7615e561-65b1-44f3-914c-c23c4a3418a9

The open-access MAF lists 13 somatic variants for this specimen: 3 protein-altering or splice-affecting, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 4, Intron 3, Missense Mutation 3, 5'UTR 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHA9 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as rs782752701, COSV65327050; called by muse, mutect2
- C2orf81 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2
- SBNO2 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCSER1 | c.2011-34776C>T | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs1226210448; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71641228 G>A | 3'Flank (SNP) | VAF 3/21 reads (14%) | catalogued as rs1050803796; called by muse, mutect2
- MEI1 | chr22:41697694 G>A | 5'Flank (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- PTEN | c.*4492G>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- RPL38 | c.*149del | 3'UTR (DEL) | VAF 18/43 reads (42%) | called by pindel, varscan2*
- SCD5 | c.*28C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- TAPT1 | c.612+369T>G | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- TLE3 | c.-1019_-1016delinsG | 5'UTR (DEL) | VAF 4/39 reads (10%) | catalogued as COSV58168191; called by pindel, varscan2*
- TMEM164 | c.*1030C>A | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- ZNF695 | c.259+3248G>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
